Somatic mutation profile of tumor specimen ALCH-AFEU-TTP1-A (aliquot ALCH-AFEU-TTP1-A-2-0-D-A678-36) from ALCHEMIST case ALCH-AFEU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.3 years (20,191 days).
Specimen ALCH-AFEU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fc1a56e-2c54-4bdd-aa99-044cccf870d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFEU-NB1-A (Blood Derived Normal), aliquot ALCH-AFEU-NB1-A-1-0-D-A678-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/879c195f-a795-4acd-a190-a26c535010a5

The open-access MAF lists 572 somatic variants for this specimen: 402 protein-altering or splice-affecting, 108 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 345, Silent 108, Nonsense Mutation 36, Intron 30, RNA 12, 5'UTR 7, 5'Flank 7, Splice Site 6, 3'UTR 6, Splice Region 6, Frame Shift Del 5, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 108/1067 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 46/206 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13598G>A p.R4533H | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747899889, COSV68944659; called by muse, mutect2
- ABCB6 | c.1993C>T p.H665Y | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as COSV54696961; called by muse, mutect2, varscan2
- ABCD1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs782458499, COSV99497292; called by muse, mutect2, varscan2
- ADAMTS3 | c.1624T>C p.W542R | Missense Mutation (SNP) | VAF 42/566 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs964826618, COSV54385432; called by muse, mutect2
- ADD2 | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 30/434 reads (7%) | catalogued as rs1553372680; called by muse, mutect2
- ADD3 | c.1585A>G p.I529V | Missense Mutation (SNP) | VAF 37/753 reads (5%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as COSV53322984; called by muse, mutect2
- AGPAT2 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV58247708; called by muse, mutect2
- BMPR1B | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 41/340 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV52774805; called by muse, mutect2, varscan2
- BMS1 | c.1028G>T p.G343V | Missense Mutation (SNP) | VAF 90/459 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65735032; called by muse, mutect2, varscan2
- BNC2 | c.3054A>T p.E1018D | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV66168138; called by muse, mutect2
- BRCA2 | c.6280T>C p.Y2094H | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as CD063467; called by muse, mutect2, varscan2
- C4B | c.3616C>A p.P1206T | Missense Mutation (SNP) | VAF 129/746 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV101312159; called by muse, mutect2, varscan2
- CABIN1 | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 38/546 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs372897703, COSV99573478; called by muse, mutect2
- CADM2 | c.641C>A p.P214H (on ENST00000407528 / NM_001167674.2; = p.P216H on NM_153184.4) | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV67388230; called by muse, mutect2
- CCT8L2 | c.1358C>A p.A453E | Missense Mutation (SNP) | VAF 78/485 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63462909; called by muse, mutect2, varscan2
- CDH10 | c.1406A>T p.E469V | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV52591541; called by muse, mutect2, varscan2
- CDH12 | c.302T>G p.V101G | Missense Mutation (SNP) | VAF 23/412 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV66418941; called by muse, mutect2
- CDH7 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 80/710 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100542242; called by muse, mutect2, varscan2
- CDH9 | c.991G>T p.V331F | Missense Mutation (SNP) | VAF 62/714 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV50282457, COSV99142338; called by muse, mutect2
- CDYL2 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 24/244 reads (10%) | catalogued as COSV101629637; called by muse, mutect2
- CFAP54 | c.8753C>T p.T2918M | Missense Mutation (SNP) | VAF 34/511 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs993186631, COSV73047386; called by muse, mutect2
- CFH | c.2666A>G p.E889G | Missense Mutation (SNP) | VAF 83/870 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100809855; called by muse, mutect2, varscan2
- CLNK | c.1234C>G p.Q412E | Missense Mutation (SNP) | VAF 48/722 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV57019197; called by muse, mutect2
- CNTNAP2 | c.3047G>C p.R1016P | Missense Mutation (SNP) | VAF 110/615 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.578); catalogued as COSV62265209; called by muse, mutect2, varscan2
- CPNE9 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs1408632297, COSV56069034; called by muse, mutect2, varscan2
- CROT | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 71/457 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146906054; called by muse, mutect2, varscan2
- CUBN | c.902A>G p.Y301C | Missense Mutation (SNP) | VAF 42/994 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1247314022; called by muse, mutect2
- CUL7 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 139/708 reads (20%) | catalogued as COSV54814544; called by muse, mutect2, varscan2
- CYP4F3 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as rs1164971245, COSV55414035; called by muse, mutect2
- DCAF12L2 | c.1192G>T p.A398S | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV63582809; called by muse, mutect2, varscan2
- DNAH3 | c.6697G>T p.G2233W | Missense Mutation (SNP) | VAF 38/484 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54559582; called by muse, mutect2
- DNMT3A | c.1681G>T p.E561* | Nonsense Mutation (SNP) | VAF 17/101 reads (17%) | catalogued as COSV53081255; called by muse, mutect2, varscan2
- EPB41L3 | c.3175G>A p.E1059K | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100550319, COSV59465601; called by muse, mutect2
- EPB41L3 | c.1610G>T p.C537F | Missense Mutation (SNP) | VAF 18/418 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100550355; called by muse, mutect2
- EPHA3 | c.2142C>A p.H714Q | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV60698665, COSV60720347; called by muse, mutect2, varscan2
- ERC2 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 42/452 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs369150569; called by muse, mutect2
- ESYT3 | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs199809846; called by muse, mutect2
- EXOC4 | c.481G>T p.V161F | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs146409877; called by muse, mutect2, varscan2
- FANCB | c.1967A>G p.H656R | Missense Mutation (SNP) | VAF 72/870 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1301627510; called by muse, mutect2
- FBLN1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 20/352 reads (6%) | catalogued as rs1169120464; called by muse, mutect2
- FGD6 | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 32/642 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV59697126; called by muse, mutect2
- FKTN | c.166-7C>G | Splice Region (SNP) | VAF 22/346 reads (6%) | catalogued as rs1005505821; called by muse, mutect2
- FLNA | c.6253G>T p.E2085* (on ENST00000369850 / NM_001110556.2; = p.E2077* on NM_001456.3) | Nonsense Mutation (SNP) | VAF 31/306 reads (10%) | catalogued as COSV104420191; called by muse, mutect2, varscan2
- FNDC7 | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs376320774; called by muse, varscan2
- FRAS1 | c.9155G>A p.R3052Q | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs779370839, COSV53609737; called by muse, mutect2, varscan2
- GDF1 | c.242C>A p.T81K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.03); catalogued as COSV99438807; called by muse, mutect2, varscan2
- GRIA1 | c.2521G>C p.G841R | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.039); catalogued as COSV53592397; called by muse, mutect2
- GRM6 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51447712; called by muse, mutect2, varscan2
- HMCN2 | c.427G>C p.A143P | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70279975; called by muse, mutect2
- HSPG2 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 30/464 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as rs560206345, COSV65929952; called by muse, mutect2
- INSR | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs2162771; called by muse, mutect2
- ISL1 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 83/1006 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.175); catalogued as COSV57933302; called by muse, mutect2
- JHY | c.1750A>G p.S584G | Missense Mutation (SNP) | VAF 35/435 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1355774038, COSV57080952; called by muse, mutect2
- KCNB2 | c.2516G>C p.S839T | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as COSV101578733; called by muse, mutect2, varscan2
- KDM3B | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 33/291 reads (11%) | catalogued as COSV58688180; called by muse, mutect2, varscan2
- KIF2B | c.1430C>A p.A477D | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771942045, COSV52127680; called by muse, mutect2, varscan2
- KIRREL3 | c.1165C>A p.R389S | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.148); catalogued as COSV69384154; called by muse, mutect2
- KMT2B | c.5012A>G p.Y1671C | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99719671; called by muse, mutect2
- KRTAP10-9 | c.421T>C p.C141R | Missense Mutation (SNP) | VAF 40/414 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs781880780; called by muse, mutect2
- LDHB | c.706G>T p.V236F | Missense Mutation (SNP) | VAF 40/578 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63365010; called by muse, mutect2
- LGR5 | c.2428C>A p.P810T | Missense Mutation (SNP) | VAF 27/684 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57002959; called by muse, mutect2
- LRRK2 | c.4900T>G p.F1634V | Missense Mutation (SNP) | VAF 19/527 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.301); catalogued as COSV100111317; called by muse, mutect2
- MAOA | c.1270C>A p.R424S | Missense Mutation (SNP) | VAF 44/684 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV58645493; called by muse, mutect2
- MRC2 | c.3583C>T p.R1195W | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs1446902653; called by muse, mutect2
- MS4A18 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 64/510 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.559); catalogued as rs940763441; called by muse, mutect2, varscan2
- MTUS2 | c.3466A>G p.I1156V (on ENST00000612955 / NM_001366650.1; = p.I135V on NM_015233.6) | Missense Mutation (SNP) | VAF 83/411 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as COSV60158088; called by muse, mutect2, varscan2
- MUC12 | c.1645G>T p.A549S (on ENST00000379442; = p.A406S on NM_001164462.1) | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.753); catalogued as rs759917649; called by muse, mutect2
- MUC16 | c.7372C>T p.P2458S | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs779148410, COSV67469349; called by muse, mutect2, varscan2
- MXRA5 | c.2648C>T p.P883L | Missense Mutation (SNP) | VAF 39/401 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs150373644; called by muse, mutect2
- MYO7A | c.3176C>T p.T1059I | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1555085481, COSV101289074; called by muse, mutect2, varscan2
- MYT1L | c.2871C>G p.C957W | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67704147; called by muse, varscan2
- NBEA | c.4604A>G p.D1535G | Missense Mutation (SNP) | VAF 28/692 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs1181986638; called by muse, mutect2
- NCKAP5 | c.3566A>C p.K1189T | Missense Mutation (SNP) | VAF 22/438 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as COSV100495190; called by muse, mutect2
- NEFH | c.1165C>T p.L389F | Missense Mutation (SNP) | VAF 30/513 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV60219450; called by muse, mutect2
- NHLRC3 | c.507A>T p.L169F | Missense Mutation (SNP) | VAF 38/806 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs1407858244; called by muse, mutect2
- NME8 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 100/768 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99553440; called by muse, mutect2
- NRG3 | c.1972G>C p.V658L (on ENST00000404547 / NM_001370084.1; = p.V634L on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/371 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100931268; called by muse, mutect2, varscan2
- NRXN1 | c.2392C>T p.L798F | Missense Mutation (SNP) | VAF 52/372 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs1393239626, COSV58452321, COSV58462624; called by muse, mutect2, varscan2
- OCRL | c.1631G>T p.R544L | Missense Mutation (SNP) | VAF 62/659 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV100843351; called by muse, mutect2
- OR10D3 | c.722G>A p.C241Y | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs931313830; called by muse, mutect2
- OR10J5 | c.491T>A p.F164Y | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750344586; called by muse, mutect2
- OR4C46 | c.274T>C p.F92L | Missense Mutation (SNP) | VAF 56/635 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.065); catalogued as rs1159074837; called by muse, mutect2
- OR4N2 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 100/1178 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV60051264; called by muse, mutect2
- OSBPL11 | c.692A>G p.Q231R | Missense Mutation (SNP) | VAF 42/357 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as rs762471538; called by muse, mutect2, varscan2
- P4HA3 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV59042316; called by muse, mutect2, varscan2
- PCDH11X | c.1571T>C p.V524A | Missense Mutation (SNP) | VAF 89/955 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs775010266; called by muse, mutect2
- PCDH11X | c.4009G>T p.G1337C | Missense Mutation (SNP) | VAF 108/1110 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.671); catalogued as COSV53443856; called by muse, mutect2
- PCDH7 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1183255902; called by muse, mutect2
- PGAP1 | c.451A>G p.I151V | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.653); catalogued as rs1244957448; called by muse, mutect2, varscan2
- PLA2G2F | c.47T>C p.V16A | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1243565537; called by muse, mutect2
- PLVAP | c.632G>T p.R211L | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV53084155; called by muse, mutect2, varscan2
- PLVAP | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs772839272, COSV53087213; called by muse, mutect2, varscan2
- PLXNA4 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 68/454 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58138152; called by muse, mutect2, varscan2
- PRR30 | c.587T>C p.V196A | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV53207568; called by muse, mutect2
- PXDNL | c.4120G>T p.E1374* | Nonsense Mutation (SNP) | VAF 48/524 reads (9%) | catalogued as rs776617130, CM1410446; called by muse, mutect2
- RASL10B | c.306C>A p.Y102* | Nonsense Mutation (SNP) | VAF 35/171 reads (20%) | catalogued as rs146982096; called by muse, mutect2, varscan2
- RAVER1 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 21/349 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.051); catalogued as COSV53343767; called by muse, mutect2
- RIMS2 | c.2183C>A p.S728* (on ENST00000666250 / NM_001348490.2; = p.S536* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 34/346 reads (10%) | catalogued as COSV51670807, COSV51686513; called by muse, mutect2
- RNF32 | c.916C>G p.Q306E | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as rs766097316; called by muse, mutect2
- RTL1 | c.3584C>T p.T1195M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs377347537; called by muse, mutect2, varscan2
- RTP1 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV99044213; called by muse, mutect2, varscan2
- RXFP3 | c.1047C>A p.S349R | Missense Mutation (SNP) | VAF 40/584 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV100347339; called by muse, mutect2
- SALL1 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 22/289 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs779513054, COSV51763776; called by muse, mutect2
- SEMA5A | c.1803G>A p.W601* | Nonsense Mutation (SNP) | VAF 36/456 reads (8%) | catalogued as COSV66804852; called by muse, mutect2
- SIGLEC11 | c.1357G>T p.V453L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs369116394, COSV70221867; called by muse, mutect2
- SIGLEC8 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs769305269; called by muse, varscan2
- SLC23A3 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs561077526, COSV55407103; called by muse, mutect2
- SLC35B3 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 38/308 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs764533271, COSV104428254; called by muse, varscan2
- SP4 | c.1087C>G p.Q363E | Missense Mutation (SNP) | VAF 55/472 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.094); catalogued as rs370914140; called by muse, mutect2, varscan2
- STAG2 | c.1811G>T p.R604L | Missense Mutation (SNP) | VAF 46/468 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV54366336, COSV54372751; called by muse, mutect2
- SYNJ2BP | c.265G>T p.G89C | Missense Mutation (SNP) | VAF 16/337 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99832556; called by muse, mutect2
- TARS3 | c.1847G>C p.G616A | Missense Mutation (SNP) | VAF 40/439 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100255095; called by muse, mutect2
- TAS2R16 | c.622C>A p.Q208K | Missense Mutation (SNP) | VAF 46/478 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.065); catalogued as rs1207059482, COSV50797227; called by muse, mutect2
- TCERG1L | c.1101G>A p.W367* | Nonsense Mutation (SNP) | VAF 60/286 reads (21%) | catalogued as rs779440528; called by muse, mutect2, varscan2
- TENM2 | c.5984C>T p.S1995L (on ENST00000518659 / NM_001122679.2; = p.S1756L on NM_001080428.3) | Missense Mutation (SNP) | VAF 32/365 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs749412027, COSV69123809; called by muse, mutect2
- TMEM132C | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV70658337; called by muse, mutect2
- TMEM186 | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 62/780 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as rs776766705, COSV99191176; called by muse, mutect2
- TMPRSS5 | c.328+3G>T | Splice Region (SNP) | VAF 18/188 reads (10%) | catalogued as COSV55426034; called by muse, mutect2
- TOPAZ1 | c.3536T>G p.L1179W | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1325612566; called by muse, mutect2
- TPR | c.5990G>A p.G1997D | Missense Mutation (SNP) | VAF 58/487 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.705); catalogued as COSV100823789; called by muse, mutect2, varscan2
- TPTE | c.347C>A p.T116N (on ENST00000618007 / NM_199261.4; = p.T98N on NM_199259.4) | Missense Mutation (SNP) | VAF 42/974 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1333264546; called by muse, mutect2
- TRIM11 | c.1117G>T p.A373S | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV52858731; called by muse, mutect2
- TRIM49B | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 41/436 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60320976; called by muse, mutect2
- TRIM49B | c.958T>A p.Y320N | Missense Mutation (SNP) | VAF 38/736 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV60321446; called by muse, mutect2
- TRIM58 | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775669996, COSV100825217, COSV63569216; called by muse, mutect2
- TRIM67 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs1054851385; called by muse, mutect2
- TRPA1 | c.1729A>T p.N577Y | Missense Mutation (SNP) | VAF 22/749 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104384982; called by muse, mutect2
- TSHZ3 | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.214); catalogued as rs749934824; called by muse, mutect2, varscan2
- TXNDC11 | c.685C>T p.L229F | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV51597569; called by muse, mutect2, varscan2
- VPS13A | c.7082G>T p.R2361M | Missense Mutation (SNP) | VAF 79/558 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1372664900, COSV100652444; called by muse, mutect2, varscan2
- WASHC2C | c.3021del p.S1008Vfs*6 (on ENST00000336378; = p.S987Vfs*6 on NM_015262.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 14/93 reads (15%) | catalogued as COSV100314174; called by mutect2, varscan2
- WDR45 | c.828-1G>A p.X276_splice (on ENST00000376372 / NM_001029896.2; = p.X277_splice on NM_007075.3) | Splice Site (SNP) | VAF 13/94 reads (14%) | catalogued as CS160963; called by muse, mutect2, varscan2
- WDR97 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs1201245574; called by muse, mutect2
- XIRP2 | c.117C>G p.H39Q (on ENST00000628543; = p.H214Q on NM_152381.6) | Missense Mutation (SNP) | VAF 38/371 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776200202, CM142669; called by muse, mutect2, varscan2
- ZC3H12B | c.2057C>G p.P686R | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV59049994; called by muse, mutect2, varscan2
- ZFHX4 | c.7769G>C p.C2590S | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0.078); catalogued as COSV50508533; called by muse, mutect2
- ZNF92 | c.968G>T p.R323I (on ENST00000328747 / NM_152626.4; = p.R254I on NM_007139.4) | Missense Mutation (SNP) | VAF 18/422 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.374); catalogued as COSV100165623; called by muse, mutect2
- AARS1 | c.2308T>A p.L770M | Missense Mutation (SNP) | VAF 40/604 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); called by muse, mutect2
- AC006059.2 | c.895G>T p.V299F | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, varscan2
- AC244197.3 | c.736C>A p.P246T | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- ACE | c.1789C>A p.Q597K | Missense Mutation (SNP) | VAF 32/401 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0.114); called by muse, mutect2
- ADAM22 | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 47/315 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ADAMTS18 | c.3064G>C p.A1022P | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2
- ADAMTS19 | c.158_159insT p.V54Gfs*65 | Frame Shift Ins (INS) | VAF 8/71 reads (11%) | called by mutect2, varscan2
- ADGRA1 | c.903G>T p.R301S | Missense Mutation (SNP) | VAF 31/269 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- AKR1B10 | c.47T>A p.V16E | Missense Mutation (SNP) | VAF 21/423 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- AL713999.2 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 44/429 reads (10%) | called by muse, mutect2
- ANKMY1 | c.1471C>T p.Q491* | Nonsense Mutation (SNP) | VAF 24/266 reads (9%) | called by muse, mutect2
- ANKRD30A | c.3863A>T p.Q1288L (on ENST00000611781; = p.Q1232L on NM_052997.2) | Missense Mutation (SNP) | VAF 107/1067 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD50 | c.2543G>T p.W848L | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- AP3B1 | c.1240A>T p.K414* | Nonsense Mutation (SNP) | VAF 93/984 reads (9%) | called by muse, mutect2
- ARFGEF2 | c.286G>C p.A96P | Missense Mutation (SNP) | VAF 22/698 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGAP33 | c.1478G>T p.R493L | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- ARHGEF17 | c.5438C>A p.T1813N | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.14); called by muse, mutect2
- ARMCX1 | c.900G>C p.L300F | Missense Mutation (SNP) | VAF 49/417 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARMCX3 | c.130G>T p.G44W | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- ASTN2 | c.2605A>T p.S869C (on ENST00000313400 / NM_001365069.1; = p.S818C on NM_014010.5) | Missense Mutation (SNP) | VAF 39/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP10D | c.3578C>T p.P1193L | Missense Mutation (SNP) | VAF 48/500 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.056); called by muse, mutect2
- ATRX | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- BACH2 | c.864C>A p.S288R | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.386); called by muse, mutect2
- BICD2 | c.2295G>T p.Q765H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BIRC6 | c.10478A>G p.H3493R | Missense Mutation (SNP) | VAF 34/840 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- BOD1L1 | c.8230G>T p.D2744Y | Missense Mutation (SNP) | VAF 24/495 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- BRINP1 | c.677A>T p.H226L | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- BRWD1 | c.2128A>G p.S710G | Missense Mutation (SNP) | VAF 46/569 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2
- C6 | c.392A>C p.K131T | Missense Mutation (SNP) | VAF 27/884 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.165); called by muse, mutect2
- C7 | c.117C>A p.C39* | Nonsense Mutation (SNP) | VAF 24/484 reads (5%) | called by muse, mutect2
- C8orf87 | n.186A>G | Splice Region (SNP) | VAF 14/340 reads (4%) | called by muse, mutect2
- CACNA1F | c.2062C>T p.H688Y | Missense Mutation (SNP) | VAF 39/480 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); called by muse, mutect2
- CALB2 | c.154A>G p.R52G | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.743); called by muse, mutect2
- CALCR | c.59C>A p.T20N | Missense Mutation (SNP) | VAF 57/329 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- CCAR1 | c.1483G>T p.D495Y | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCT6A | c.1098del p.C366* | Frame Shift Del (DEL) | VAF 40/334 reads (12%) | called by pindel, varscan2
- CEMIP2 | c.541A>T p.I181F | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- CEP57 | c.167A>G p.K56R | Missense Mutation (SNP) | VAF 39/765 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.141); called by muse, mutect2
- CETP | c.1248+1G>T p.X416_splice | Splice Site (SNP) | VAF 56/664 reads (8%) | called by muse, mutect2
- CFAP54 | c.1894G>T p.A632S | Missense Mutation (SNP) | VAF 20/480 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- CFAP69 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CHD7 | c.5073G>T p.R1691S | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CHKB | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 42/696 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2
- CHRM3 | c.758G>C p.R253T | Missense Mutation (SNP) | VAF 46/459 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CLCA4 | c.1245G>T p.E415D | Missense Mutation (SNP) | VAF 32/378 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- CLCA4 | c.1246G>T p.D416Y | Missense Mutation (SNP) | VAF 32/384 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLCN1 | c.757T>C p.F253L | Missense Mutation (SNP) | VAF 28/514 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); called by muse, mutect2
- CLDN8 | c.659C>A p.S220Y | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CLEC16A | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNOT4 | c.812G>T p.R271M (on ENST00000315544 / NM_001190848.1; = p.S271I on NM_013316.4) | Missense Mutation (SNP) | VAF 68/421 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- CNTNAP3 | c.1491C>G p.N497K | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.021); called by muse, mutect2
- COL1A2 | c.1741C>T p.L581F | Missense Mutation (SNP) | VAF 127/842 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- COL6A3 | c.3373G>A p.G1125R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPED1 | c.14C>G p.P5R | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.125); called by muse, mutect2
- CPT1C | c.745A>G p.M249V | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.158); called by muse, mutect2
- CSF2RA | c.1021G>T p.V341F | Missense Mutation (SNP) | VAF 98/658 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CSMD3 | c.10619T>A p.L3540Q (on ENST00000297405 / NM_001363185.1; = p.L3371Q on NM_052900.3) | Missense Mutation (SNP) | VAF 91/843 reads (11%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CTNND2 | c.1918G>T p.A640S | Missense Mutation (SNP) | VAF 40/685 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CX3CR1 | c.349A>T p.I117L | Missense Mutation (SNP) | VAF 44/540 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); called by muse, mutect2
- CXCR2 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- DAO | c.845T>G p.F282C | Missense Mutation (SNP) | VAF 56/646 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- DCAF12L2 | c.953T>G p.L318W | Missense Mutation (SNP) | VAF 29/521 reads (6%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.594); called by muse, mutect2
- DDIAS | c.2336G>T p.G779V | Missense Mutation (SNP) | VAF 36/573 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.401); called by muse, mutect2
- DEFB132 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX34 | c.1630C>A p.P544T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DMD | c.1738G>T p.D580Y | Missense Mutation (SNP) | VAF 107/1059 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- DMD | c.1222G>T p.G408* | Nonsense Mutation (SNP) | VAF 57/678 reads (8%) | called by muse, mutect2
- DNAH5 | c.4838A>T p.Q1613L | Missense Mutation (SNP) | VAF 46/910 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, mutect2
- DNAH6 | c.7187A>T p.E2396V | Missense Mutation (SNP) | VAF 63/347 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH9 | c.5076G>T p.R1692S | Missense Mutation (SNP) | VAF 31/542 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); called by muse, mutect2
- DNAH9 | c.8296C>A p.P2766T | Missense Mutation (SNP) | VAF 40/371 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- DTHD1 | c.35C>A p.S12Y (on ENST00000456874; = p.S137Y on NM_001170700.3) | Missense Mutation (SNP) | VAF 62/900 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- EFHC2 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EHHADH | c.1622G>C p.G541A | Missense Mutation (SNP) | VAF 23/342 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); called by muse, mutect2
- ERN2 | c.1558T>A p.F520I | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- ERVH48-1 | c.343A>C p.I115L | Missense Mutation (SNP) | VAF 93/879 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EYA1 | c.1669G>T p.G557C | Missense Mutation (SNP) | VAF 71/751 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM184B | c.582G>C p.Q194H | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by mutect2, varscan2
- FAT1 | c.12631A>T p.K4211* | Nonsense Mutation (SNP) | VAF 30/411 reads (7%) | called by muse, mutect2
- FAT2 | c.7391C>A p.T2464N | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- FAT4 | c.12748G>A p.V4250I | Missense Mutation (SNP) | VAF 108/804 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.011); called by muse, varscan2
- FBN2 | c.8548A>G p.R2850G | Missense Mutation (SNP) | VAF 34/352 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.212); called by muse, mutect2
- FBN2 | c.1360G>T p.G454* | Nonsense Mutation (SNP) | VAF 41/513 reads (8%) | called by muse, mutect2
- FEZF1 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 20/670 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2
- FKBP6 | c.474G>T p.Q158H | Missense Mutation (SNP) | VAF 49/664 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2
- FLG | c.3588C>G p.S1196R | Missense Mutation (SNP) | VAF 40/610 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- FLNC | c.1154T>A p.L385Q | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- FOXN3 | c.866C>T p.P289L (on ENST00000261302; = p.P267L on NM_005197.4) | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- FRMPD3 | c.2188C>A p.L730M | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); called by muse, varscan2
- FSD1L | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- FSIP2 | c.14371C>A p.H4791N | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.223); called by muse, mutect2
- FSTL5 | c.1356C>G p.N452K | Missense Mutation (SNP) | VAF 43/342 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- GABRA4 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- GBA | c.1413G>T p.Q471H | Missense Mutation (SNP) | VAF 48/574 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.035); called by muse, mutect2
- GIMAP8 | c.121A>T p.S41C | Missense Mutation (SNP) | VAF 24/939 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- GLRA4 | c.576C>A p.S192R | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- GNS | c.879del p.W293Cfs*46 | Frame Shift Del (DEL) | VAF 77/592 reads (13%) | called by mutect2, pindel, varscan2
- GRIN3A | c.529C>A p.P177T | Missense Mutation (SNP) | VAF 58/758 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- GTSE1 | c.2125G>A p.V709M | Missense Mutation (SNP) | VAF 43/330 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- HECW1 | c.3537G>C p.E1179D | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- HEPACAM2 | c.195G>T p.Q65H (on ENST00000394468 / NM_001039372.4; = p.Q53H on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/632 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- HEPACAM2 | c.136G>T p.G46C (on ENST00000394468 / NM_001039372.4; = p.G34C on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/562 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HFM1 | c.1559T>G p.V520G | Missense Mutation (SNP) | VAF 20/640 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- HMCN1 | c.3506-2A>T p.X1169_splice | Splice Site (SNP) | VAF 35/492 reads (7%) | called by muse, mutect2
- HMGN5 | c.665A>C p.E222A | Missense Mutation (SNP) | VAF 38/578 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.132); called by muse, mutect2
- HOXA1 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 16/317 reads (5%) | called by muse, mutect2
- IFI44L | c.164A>T p.Y55F | Missense Mutation (SNP) | VAF 46/397 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- IGSF8 | c.1766G>T p.G589V | Missense Mutation (SNP) | VAF 36/478 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.054); called by muse, mutect2
- IP6K2 | c.240G>T p.R80S | Missense Mutation (SNP) | VAF 46/452 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- ISLR | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 9/89 reads (10%) | called by mutect2, varscan2
- ITGA4 | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 39/470 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- KAT6B | c.3950C>T p.A1317V | Missense Mutation (SNP) | VAF 70/537 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- KCNC2 | c.1305G>C p.M435I | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- KIAA1549L | c.3542G>T p.W1181L (on ENST00000321505; = p.W1478L on NM_012194.3) | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- KIF4A | c.387G>C p.K129N | Missense Mutation (SNP) | VAF 42/360 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LOXHD1 | c.3974dup p.N1325Kfs*31 | Frame Shift Ins (INS) | VAF 36/221 reads (16%) | called by mutect2, pindel, varscan2
- LRP1B | c.5438T>A p.I1813N | Missense Mutation (SNP) | VAF 17/444 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.095); called by muse, mutect2
- MAGEC3 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 34/315 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MAP10 | c.494C>A p.A165D | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MCM2 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MED12 | c.3494C>G p.S1165C | Missense Mutation (SNP) | VAF 28/770 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- MED14 | c.1321C>A p.P441T | Missense Mutation (SNP) | VAF 30/470 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2
- MORC1 | c.2803G>T p.G935C | Missense Mutation (SNP) | VAF 51/536 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- MPP7 | c.1171A>G p.S391G | Missense Mutation (SNP) | VAF 32/596 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2
- MROH2A | c.1842G>T p.M614I | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- MROH5 | c.358C>A p.P120T | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTMR1 | c.1651A>T p.K551* | Nonsense Mutation (SNP) | VAF 47/291 reads (16%) | called by muse, mutect2, varscan2
- MUC16 | c.4618C>A p.L1540M | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- NDUFAF4 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2
- NEXMIF | c.4235G>C p.R1412P | Missense Mutation (SNP) | VAF 44/466 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2
- NF1 | c.5245A>T p.K1749* (on ENST00000358273 / NM_001042492.3; = p.K1728* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 44/257 reads (17%) | called by muse, mutect2, varscan2
- NFKB2 | c.2023G>T p.A675S | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- NFRKB | c.2481G>T p.L827F (on ENST00000446488 / NM_001143835.2; = p.L852F on NM_006165.3) | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.648); called by muse, mutect2
- NKX2-1 | c.47T>C p.I16T | Missense Mutation (SNP) | VAF 76/623 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- NLGN3 | c.1180G>T p.G394C (on ENST00000358741 / NM_181303.2; = p.G374C on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/415 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NME8 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 97/758 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NPAS1 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 24/126 reads (19%) | called by muse, mutect2, varscan2
- NSD1 | c.3401G>T p.G1134V | Missense Mutation (SNP) | VAF 22/345 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- NUB1 | c.70+3G>A | Splice Region (SNP) | VAF 12/114 reads (11%) | called by muse, mutect2, varscan2
- OGDH | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 56/609 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.29); called by muse, mutect2
- OR10Q1 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); called by muse, mutect2
- OR13G1 | c.246G>T p.M82I | Missense Mutation (SNP) | VAF 56/714 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2
- OR2M2 | c.551T>A p.L184Q | Missense Mutation (SNP) | VAF 39/567 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR4F15 | c.539A>T p.D180V | Missense Mutation (SNP) | VAF 15/265 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR4S2 | c.805G>T p.V269L | Missense Mutation (SNP) | VAF 46/452 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR51B4 | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 32/321 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR51G2 | c.176C>A p.S59* | Nonsense Mutation (SNP) | VAF 24/285 reads (8%) | called by muse, mutect2
- OR51S1 | c.92C>A p.A31E | Missense Mutation (SNP) | VAF 23/265 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.029); called by muse, mutect2
- OR6C75 | c.14C>G p.T5R | Missense Mutation (SNP) | VAF 22/349 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.544); called by muse, mutect2
- OR6V1 | c.458C>G p.A153G | Missense Mutation (SNP) | VAF 65/394 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- OR9G1 | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 37/542 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2
- OTOG | c.2129T>C p.V710A | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- OTUB1 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.303); called by muse, mutect2
- P4HA1 | c.1021C>T p.H341Y | Missense Mutation (SNP) | VAF 100/673 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PABPC5 | c.724G>T p.G242* | Nonsense Mutation (SNP) | VAF 58/592 reads (10%) | called by muse, mutect2
- PABPC5 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 56/594 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAPOLB | c.377A>T p.D126V | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2
- PCBP2 | c.591G>A p.Q197= | Splice Region (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- PCDH11X | c.2188A>T p.T730S | Missense Mutation (SNP) | VAF 50/650 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0.044); called by muse, mutect2
- PCDH15 | c.3521G>T p.G1174V | Missense Mutation (SNP) | VAF 126/878 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA6 | c.1697T>C p.L566P | Missense Mutation (SNP) | VAF 33/514 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2
- PDCD6IP | c.1538A>G p.Y513C | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PDGFRA | c.3157G>T p.G1053C | Missense Mutation (SNP) | VAF 71/737 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDK3 | c.431G>T p.S144I | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.281); called by muse, mutect2
- PER3 | c.1553A>T p.Y518F | Missense Mutation (SNP) | VAF 50/554 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.103); called by muse, mutect2
- PHEX | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 92/1126 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.006); called by muse, mutect2
- PHF14 | c.2234C>T p.T745I | Missense Mutation (SNP) | VAF 76/554 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- PHKB | c.413A>G p.Q138R | Missense Mutation (SNP) | VAF 34/886 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.044); called by muse, mutect2
- PKD1L1 | c.3527A>T p.K1176M | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- PLEKHA5 | c.2622G>T p.K874N | Missense Mutation (SNP) | VAF 53/346 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PLEKHS1 | c.139G>T p.G47W (on ENST00000369310 / NM_182601.1; = p.G53W on NM_024889.5) | Missense Mutation (SNP) | VAF 34/520 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PLXNC1 | c.1844G>T p.C615F | Missense Mutation (SNP) | VAF 38/590 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- POLK | c.2311G>T p.V771L | Missense Mutation (SNP) | VAF 33/319 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POMGNT2 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- POTEE | c.1900-1G>T p.X634_splice | Splice Site (SNP) | VAF 93/570 reads (16%) | called by muse, mutect2, varscan2
- PPP4R3C | c.1295G>C p.G432A | Missense Mutation (SNP) | VAF 66/651 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- PRDM9 | c.1021T>C p.Y341H | Missense Mutation (SNP) | VAF 74/900 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- PRDM9 | c.1200G>T p.Q400H | Missense Mutation (SNP) | VAF 152/829 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- PSG3 | c.754A>T p.R252W | Missense Mutation (SNP) | VAF 38/299 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PSG6 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 96/523 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- PSMD4 | c.922A>G p.I308V | Missense Mutation (SNP) | VAF 54/646 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- PUS7 | c.419A>T p.H140L | Missense Mutation (SNP) | VAF 53/347 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- PVRIG | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 51/369 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PXDNL | c.3172A>T p.T1058S | Missense Mutation (SNP) | VAF 102/960 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- RABEP1 | c.811del p.Q271Nfs*6 | Frame Shift Del (DEL) | VAF 30/240 reads (13%) | called by mutect2, pindel, varscan2
- RADX | c.358C>A p.Q120K | Missense Mutation (SNP) | VAF 84/828 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASAL3 | c.913T>C p.W305R | Missense Mutation (SNP) | VAF 12/291 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); called by muse, mutect2
- RCBTB1 | c.546G>T p.R182S | Missense Mutation (SNP) | VAF 32/469 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.065); called by muse, mutect2
- REG3G | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 19/365 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RELN | c.1849C>A p.H617N | Missense Mutation (SNP) | VAF 113/621 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- RET | c.1051G>T p.V351L | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RIDA | c.352-2A>G p.X118_splice | Splice Site (SNP) | VAF 13/259 reads (5%) | called by muse, mutect2
- RORA | c.810G>A p.M270I (on ENST00000335670 / NM_134261.3; = p.M295I on NM_002943.3) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SACS | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 98/744 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SAFB | c.1280G>T p.S427I | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SAMD9 | c.1896G>T p.L632F | Missense Mutation (SNP) | VAF 35/512 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SI | c.4624T>C p.C1542R | Missense Mutation (SNP) | VAF 194/823 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- SLC20A1 | c.646A>T p.T216S | Missense Mutation (SNP) | VAF 46/480 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.05); called by muse, mutect2
- SLC25A24 | c.310G>T p.G104* | Nonsense Mutation (SNP) | VAF 36/616 reads (6%) | called by muse, mutect2
- SLC25A44 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLC4A8 | c.2675C>G p.S892* | Nonsense Mutation (SNP) | VAF 24/280 reads (9%) | called by muse, mutect2
- SLC8A1 | c.1147G>T p.A383S | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SLF1 | c.2180A>T p.Q727L | Missense Mutation (SNP) | VAF 67/625 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SLX4 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 40/572 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2
- SMARCA4 | c.1363A>T p.K455* | Nonsense Mutation (SNP) | VAF 37/277 reads (13%) | called by muse, mutect2, varscan2
- SMIM17 | c.353T>A p.I118N | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- SPATA31A1 | c.2943G>T p.E981D | Missense Mutation (SNP) | VAF 68/1070 reads (6%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.655); called by muse, mutect2
- SPTA1 | c.1138G>T p.D380Y | Missense Mutation (SNP) | VAF 112/1142 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2
- SSH1 | c.1869G>C p.K623N | Missense Mutation (SNP) | VAF 55/386 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SSU72P8 | c.392T>C p.F131S | Missense Mutation (SNP) | VAF 52/299 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ST18 | c.1004T>A p.L335Q | Missense Mutation (SNP) | VAF 13/331 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2
- STK11IP | c.1924C>T p.Q642* | Nonsense Mutation (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- STRN3 | c.1409G>T p.W470L (on ENST00000357479 / NM_001083893.2; = p.W386L on NM_014574.4) | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- STXBP5L | c.2350G>T p.G784* | Nonsense Mutation (SNP) | VAF 49/407 reads (12%) | called by muse, mutect2, varscan2
- SUMF1 | c.1085G>A p.R362K | Missense Mutation (SNP) | VAF 24/310 reads (8%) | PolyPhen benign (0.001); called by muse, mutect2
- SZT2 | c.3263C>T p.A1088V (on ENST00000634258 / NM_001365999.1; = p.A1031V on NM_015284.4) | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- TARBP1 | c.4627G>T p.V1543L | Missense Mutation (SNP) | VAF 54/643 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2
- TAS2R16 | c.623A>T p.Q208L | Missense Mutation (SNP) | VAF 42/466 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.245); called by muse, mutect2
- TAT | c.1003C>A p.P335T | Missense Mutation (SNP) | VAF 64/795 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- TBC1D31 | c.1384C>G p.L462V | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- TDRD7 | c.2515G>T p.A839S | Missense Mutation (SNP) | VAF 81/671 reads (12%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- TECTA | c.500A>T p.Q167L | Missense Mutation (SNP) | VAF 26/554 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TENM1 | c.7822A>T p.M2608L | Missense Mutation (SNP) | VAF 52/480 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TENM4 | c.4565A>G p.D1522G | Missense Mutation (SNP) | VAF 32/490 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2
- TEX11 | c.438A>T p.Q146H (on ENST00000344304; = p.Q131H on NM_031276.3) | Missense Mutation (SNP) | VAF 54/615 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.051); called by muse, mutect2
- TEX37 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 24/407 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.082); called by muse, mutect2
- TFRC | c.1237G>C p.G413R | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGFB1I1 | c.109T>A p.S37T (on ENST00000394863 / NM_001042454.3; = p.S20T on NM_015927.4) | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.011); called by muse, mutect2
- THEM5 | c.397T>C p.F133L | Missense Mutation (SNP) | VAF 38/471 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.03); called by muse, mutect2
- THSD7A | c.1928G>T p.W643L | Missense Mutation (SNP) | VAF 20/401 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- THSD7A | c.959A>G p.Q320R | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- TMEM185A | c.1045C>A p.P349T | Missense Mutation (SNP) | VAF 38/720 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMEM221 | c.619A>T p.R207* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- TMPRSS11B | c.35G>T p.W12L | Missense Mutation (SNP) | VAF 65/568 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMPRSS5 | c.328+4G>T | Splice Region (SNP) | VAF 18/183 reads (10%) | called by muse, mutect2
- TNMD | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 26/258 reads (10%) | called by muse, mutect2
- TNRC18 | c.7437G>T p.E2479D | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TNRC6B | c.4811G>T p.G1604V (on ENST00000454349 / NM_001162501.2; = p.G1494V on NM_015088.3) | Missense Mutation (SNP) | VAF 44/391 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRAPPC10 | c.2713A>G p.R905G | Missense Mutation (SNP) | VAF 41/393 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC21B | c.3102G>T p.W1034C | Missense Mutation (SNP) | VAF 69/760 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- TTLL6 | c.1162T>G p.C388G (on ENST00000393382 / NM_001130918.3; = p.C81G on NM_173623.3) | Missense Mutation (SNP) | VAF 73/460 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGT3A1 | c.967C>A p.L323I | Missense Mutation (SNP) | VAF 48/694 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.889); called by muse, mutect2
- URB1 | c.4465C>G p.L1489V | Missense Mutation (SNP) | VAF 28/569 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2
- USH2A | c.14556del p.M4853Cfs*31 | Frame Shift Del (DEL) | VAF 47/444 reads (11%) | called by mutect2, pindel, varscan2
- USP51 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 31/579 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); called by muse, mutect2
- VAV3 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 46/472 reads (10%) | called by muse, mutect2
- VAV3 | c.649-1G>T p.X217_splice | Splice Site (SNP) | VAF 36/460 reads (8%) | called by muse, mutect2
- VAX1 | c.829G>C p.V277L | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- VCAM1 | c.194G>A p.S65N | Missense Mutation (SNP) | VAF 43/635 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.422); called by muse, mutect2
- VCP | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 48/561 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VRK2 | c.326C>G p.T109S | Missense Mutation (SNP) | VAF 21/373 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.062); called by muse, mutect2
- WDR47 | c.2256dup p.G753Wfs*24 (on ENST00000369962 / NM_001142551.2; = p.G754Wfs*24 on NM_014969.5) | Frame Shift Ins (INS) | VAF 21/198 reads (11%) | called by mutect2, pindel, varscan2
- WEE1 | c.1582C>T p.Q528* | Nonsense Mutation (SNP) | VAF 40/508 reads (8%) | called by muse, mutect2
- XIRP2 | c.6706A>T p.I2236F (on ENST00000628543; = p.I2411F on NM_152381.6) | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.216); called by muse, mutect2
- ZEB1 | c.635G>T p.R212I | Missense Mutation (SNP) | VAF 58/1278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZFPM2 | c.1724G>T p.W575L | Missense Mutation (SNP) | VAF 48/947 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF292 | c.1720T>A p.C574S | Missense Mutation (SNP) | VAF 14/433 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF574 | c.2471G>T p.C824F | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF711 | c.149T>A p.L50* | Nonsense Mutation (SNP) | VAF 73/603 reads (12%) | called by muse, mutect2, varscan2
- ZNF735 | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 38/373 reads (10%) | called by muse, mutect2, varscan2
- ZNF782 | c.233G>C p.R78T | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by mutect2, varscan2
- ZNF804B | c.236A>T p.H79L | Missense Mutation (SNP) | VAF 47/478 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZSCAN5C | c.977G>C p.G326A | Missense Mutation (SNP) | VAF 70/490 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.913); called by muse, varscan2
- ABHD16A | c.1201A>C p.R401= | Silent (SNP) | VAF 42/339 reads (12%) | called by muse, mutect2, varscan2
- ACACA | c.2319C>T p.I773= | Silent (SNP) | VAF 210/846 reads (25%) | called by muse, mutect2, varscan2
- ADAM22 | c.1854T>C p.D618= | Silent (SNP) | VAF 28/588 reads (5%) | catalogued as COSV55988232; called by muse, mutect2
- AKR1C8P | c.51C>T p.P17= | Silent (SNP) | VAF 56/443 reads (13%) | called by muse, mutect2, varscan2
- ANKRD30A | c.318C>T p.H106= (on ENST00000611781; = p.H50= on NM_052997.2) | Silent (SNP) | VAF 63/247 reads (26%) | catalogued as rs568301150; called by muse, mutect2, varscan2
- ARHGEF9 | c.1012C>A p.R338= | Silent (SNP) | VAF 22/324 reads (7%) | catalogued as CM1514576, COSV53635998; called by muse, mutect2
- ATP10B | c.1332G>T p.V444= | Silent (SNP) | VAF 23/365 reads (6%) | called by muse, mutect2
- BCL2L11 | c.573C>T p.V191= (on ENST00000393256 / NM_138621.5; = p.V131= on NM_006538.5) | Silent (SNP) | VAF 64/469 reads (14%) | called by muse, mutect2, varscan2
- BCOR | c.2886G>A p.L962= | Silent (SNP) | VAF 24/776 reads (3%) | called by muse, mutect2
- BRINP2 | c.1761C>A p.A587= | Silent (SNP) | VAF 32/344 reads (9%) | called by muse, mutect2
- C19orf84 | c.372G>C p.R124= | Silent (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- COL22A1 | c.3498A>G p.P1166= | Silent (SNP) | VAF 20/200 reads (10%) | catalogued as rs1255166219; called by muse, mutect2
- COL4A5 | c.4945C>T p.L1649= | Silent (SNP) | VAF 32/942 reads (3%) | catalogued as COSV60361529; called by muse, mutect2
- CSDE1 | c.1098G>A p.V366= (on ENST00000358528 / NM_001007553.3; = p.V335= on NM_007158.6) | Silent (SNP) | VAF 28/566 reads (5%) | called by muse, mutect2
- CSMD3 | c.3390C>A p.T1130= (on ENST00000297405 / NM_001363185.1; = p.T1026= on NM_052900.3) | Silent (SNP) | VAF 77/679 reads (11%) | called by muse, mutect2, varscan2
- CSNK1G3 | c.879A>T p.L293= | Silent (SNP) | VAF 18/264 reads (7%) | called by muse, mutect2
- DCDC1 | c.3198A>T p.V1066= (on ENST00000597505 / NM_001367979.1; = p.V173= on NM_020869.3) | Silent (SNP) | VAF 60/713 reads (8%) | called by muse, mutect2
- DDX31 | c.309G>T p.T103= | Silent (SNP) | VAF 19/208 reads (9%) | called by muse, mutect2
- DLG3 | c.553C>A p.R185= | Silent (SNP) | VAF 14/227 reads (6%) | called by muse, mutect2
- DMD | c.942G>T p.R314= | Silent (SNP) | VAF 30/1046 reads (3%) | called by muse, mutect2
- DNAAF4 | c.1134A>G p.Q378= | Silent (SNP) | VAF 49/289 reads (17%) | called by muse, mutect2, varscan2
- DSCAM | c.2934G>T p.T978= | Silent (SNP) | VAF 87/493 reads (18%) | catalogued as rs546478839; called by muse, mutect2, varscan2
- ERCC4 | c.1002G>T p.S334= | Silent (SNP) | VAF 44/505 reads (9%) | catalogued as COSV61311944; called by muse, mutect2
- ERICH6B | c.1917C>A p.I639= | Silent (SNP) | VAF 34/372 reads (9%) | catalogued as COSV100074764; called by muse, mutect2
- FAM135B | c.3924C>T p.V1308= | Silent (SNP) | VAF 31/594 reads (5%) | catalogued as rs746954728, COSV52708502; called by muse, mutect2
- FAM47A | c.1065C>A p.S355= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as rs779374074; called by muse, mutect2, varscan2
- FTCD | c.183G>T p.G61= | Silent (SNP) | VAF 50/205 reads (24%) | called by muse, mutect2, varscan2
- GALNTL5 | c.933T>A p.I311= | Silent (SNP) | VAF 117/974 reads (12%) | called by muse, mutect2, varscan2
- GJA1 | c.369G>A p.V123= | Silent (SNP) | VAF 43/1155 reads (4%) | called by muse, mutect2
- GLI1 | c.1326T>C p.P442= | Silent (SNP) | VAF 19/118 reads (16%) | called by muse, mutect2
- GREM2 | c.375C>A p.P125= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as COSV58953097; called by muse, mutect2, varscan2
- GRWD1 | c.195C>G p.P65= | Silent (SNP) | VAF 18/135 reads (13%) | called by mutect2, varscan2
- HEPH | c.522C>T p.T174= (on ENST00000343002; = p.T228= on NM_138737.5) | Silent (SNP) | VAF 43/338 reads (13%) | catalogued as rs138179187, COSV57960984, COSV57972351; called by muse, mutect2, varscan2
- HIBCH | c.777T>C p.F259= | Silent (SNP) | VAF 59/463 reads (13%) | called by muse, mutect2, varscan2
- HSD17B4 | c.477A>G p.A159= (on ENST00000414835 / NM_001199291.3; = p.A134= on NM_000414.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 105/999 reads (11%) | catalogued as rs754255447; called by muse, mutect2, varscan2
- IGHA2 | c.438C>A p.T146= | Silent (SNP) | VAF 65/518 reads (13%) | called by muse, mutect2, varscan2
- IGKV1D-16 | c.27C>G p.L9= | Silent (SNP) | VAF 54/490 reads (11%) | called by muse, mutect2, varscan2
- IGSF11 | c.259C>A p.R87= (on ENST00000393775 / NM_001015887.3; = p.R86= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/341 reads (14%) | catalogued as COSV100677804; called by mutect2, varscan2
- IL7R | c.246C>T p.C82= | Silent (SNP) | VAF 56/772 reads (7%) | called by muse, mutect2
- ITGB2 | c.2301C>G p.L767= (on ENST00000302347; = p.L743= on NM_000211.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/672 reads (7%) | called by muse, mutect2
- ITPR1 | c.6756T>C p.N2252= (on ENST00000354582; = p.N2197= on NM_002222.7) | Silent (SNP) | VAF 34/288 reads (12%) | called by muse, mutect2, varscan2
- KCNA10 | c.639C>T p.S213= | Silent (SNP) | VAF 48/399 reads (12%) | catalogued as rs374482810; called by muse, mutect2, varscan2
- KDM5B | c.2580A>G p.P860= | Silent (SNP) | VAF 35/261 reads (13%) | called by muse, mutect2, varscan2
- KDM5C | c.2739G>T p.V913= | Silent (SNP) | VAF 13/115 reads (11%) | called by muse, mutect2, varscan2
- KEL | c.336A>G p.K112= | Silent (SNP) | VAF 37/1008 reads (4%) | catalogued as rs1157446519, COSV62335821; called by muse, mutect2
- KERA | c.921C>A p.S307= | Silent (SNP) | VAF 33/615 reads (5%) | called by muse, mutect2
- LHFPL3 | c.234C>A p.G78= | Silent (SNP) | VAF 56/340 reads (16%) | catalogued as COSV67804761; called by muse, mutect2, varscan2
- LOXL1 | c.1242C>T p.Y414= | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as rs200271730, COSV56094619; called by muse, varscan2
- LRRC30 | c.576C>T p.H192= | Silent (SNP) | VAF 44/340 reads (13%) | catalogued as rs1235119199; called by muse, mutect2, varscan2
- LRRC39 | c.369A>G p.P123= | Silent (SNP) | VAF 19/196 reads (10%) | called by muse, mutect2
- LRRK1 | c.2625G>A p.L875= | Silent (SNP) | VAF 13/169 reads (8%) | called by muse, mutect2
- LRRK2 | c.5439A>G p.L1813= | Silent (SNP) | VAF 52/828 reads (6%) | called by muse, mutect2
- LRRN3 | c.1419C>T p.F473= | Silent (SNP) | VAF 22/258 reads (9%) | catalogued as rs11979902, COSV100066009, COSV57818433; called by muse, mutect2
- MAN2B1 | c.144G>C p.R48= | Silent (SNP) | VAF 26/284 reads (9%) | called by muse, mutect2
- MGAT5B | c.54C>A p.T18= | Silent (SNP) | VAF 38/519 reads (7%) | called by muse, mutect2
- MUC17 | c.10896A>G p.E3632= | Silent (SNP) | VAF 32/264 reads (12%) | called by muse, mutect2, varscan2
- NLGN4X | c.1749G>T p.R583= | Silent (SNP) | VAF 36/1090 reads (3%) | catalogued as COSV99321842; called by muse, mutect2
- NLRP3 | c.1743G>A p.L581= | Silent (SNP) | VAF 100/1320 reads (8%) | called by muse, mutect2
- NOL4 | c.591C>G p.A197= | Silent (SNP) | VAF 61/506 reads (12%) | called by muse, mutect2, varscan2
- OR11H4 | c.492T>C p.L164= | Silent (SNP) | VAF 47/389 reads (12%) | called by muse, mutect2, varscan2
- OR13G1 | c.579G>A p.E193= | Silent (SNP) | VAF 40/566 reads (7%) | catalogued as rs756910230, COSV62944036; called by muse, mutect2
- OR2T11 | c.867C>A p.L289= | Silent (SNP) | VAF 53/472 reads (11%) | called by muse, mutect2, varscan2
- OR4A16 | c.495A>T p.P165= | Silent (SNP) | VAF 38/456 reads (8%) | catalogued as rs1227735519; called by muse, mutect2
- OR6K2 | c.705C>A p.R235= | Silent (SNP) | VAF 48/468 reads (10%) | catalogued as COSV62743342; called by muse, mutect2
- ORC1 | c.1156T>C p.L386= | Silent (SNP) | VAF 95/957 reads (10%) | called by muse, mutect2
- PAX3 | c.90C>A p.S30= | Silent (SNP) | VAF 57/419 reads (14%) | called by muse, mutect2, varscan2
- PCDH11X | c.3472C>T p.L1158= | Silent (SNP) | VAF 96/1202 reads (8%) | catalogued as COSV100008620; called by muse, mutect2
- PCSK1 | c.1059C>A p.T353= | Silent (SNP) | VAF 51/518 reads (10%) | called by muse, mutect2
- PGAP3 | c.564G>T p.V188= | Silent (SNP) | VAF 28/116 reads (24%) | called by muse, varscan2
- PIGZ | c.273C>A p.R91= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2
- PIK3CG | c.2802C>A p.G934= | Silent (SNP) | VAF 82/727 reads (11%) | catalogued as COSV63249274; called by muse, mutect2, varscan2
- PNPLA6 | c.1047G>T p.L349= (on ENST00000414982 / NM_001166111.2; = p.L301= on NM_006702.5) | Silent (SNP) | VAF 18/171 reads (11%) | called by muse, mutect2
- PNPLA7 | c.612G>C p.V204= | Silent (SNP) | VAF 14/268 reads (5%) | called by muse, mutect2
- PRSS58 | c.378T>C p.T126= | Silent (SNP) | VAF 28/692 reads (4%) | catalogued as COSV73488729; called by muse, mutect2
- PSG9 | c.1206C>G p.G402= | Silent (SNP) | VAF 88/418 reads (21%) | called by muse, mutect2, varscan2
- PSMG2 | c.321T>G p.L107= | Silent (SNP) | VAF 22/172 reads (13%) | called by muse, mutect2, varscan2
- PXDNL | c.3402C>A p.A1134= | Silent (SNP) | VAF 55/420 reads (13%) | catalogued as COSV62480434; called by muse, mutect2, varscan2
- RFX3 | c.1698G>C p.L566= | Silent (SNP) | VAF 62/682 reads (9%) | called by muse, mutect2
- RYR1 | c.10293G>A p.A3431= | Silent (SNP) | VAF 35/324 reads (11%) | catalogued as rs750009828, COSV62093959; called by muse, mutect2, varscan2
- RYR2 | c.13206C>A p.L4402= | Silent (SNP) | VAF 69/739 reads (9%) | catalogued as COSV63712426; called by muse, mutect2
- RYR2 | c.14328T>G p.V4776= | Silent (SNP) | VAF 47/627 reads (7%) | called by muse, mutect2
- SCN11A | c.2073T>A p.I691= | Silent (SNP) | VAF 34/203 reads (17%) | called by muse, mutect2, varscan2
- SCYL3 | c.1872C>T p.S624= (on ENST00000367770; = p.S570= on NM_020423.7) | Silent (SNP) | VAF 23/184 reads (13%) | called by muse, mutect2, varscan2
- SERPINI2 | c.168T>G p.L56= | Silent (SNP) | VAF 30/610 reads (5%) | called by muse, mutect2
- SETD5 | c.3726G>T p.L1242= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV56707875; called by muse, varscan2
- SLC29A4 | c.402C>T p.T134= | Silent (SNP) | VAF 19/168 reads (11%) | called by muse, mutect2, varscan2
- SLC39A12 | c.993G>A p.E331= | Silent (SNP) | VAF 22/318 reads (7%) | catalogued as COSV101070080, COSV101070104; called by muse, mutect2
- SLFN14 | c.1440A>G p.G480= | Silent (SNP) | VAF 35/195 reads (18%) | called by muse, mutect2, varscan2
- SLITRK2 | c.444C>T p.A148= | Silent (SNP) | VAF 24/536 reads (4%) | catalogued as rs782649137, COSV100157552; called by muse, mutect2
- SNAI2 | c.210C>A p.P70= | Silent (SNP) | VAF 13/105 reads (12%) | called by muse, mutect2, varscan2
- SREBF2 | c.1782C>G p.A594= | Silent (SNP) | VAF 69/360 reads (19%) | called by muse, mutect2, varscan2
- SRRM2 | c.2697G>T p.V899= | Silent (SNP) | VAF 34/522 reads (7%) | called by muse, mutect2
- SYTL4 | c.663T>A p.S221= | Silent (SNP) | VAF 42/336 reads (13%) | called by muse, varscan2
- TBC1D15 | c.390C>T p.F130= | Silent (SNP) | VAF 50/880 reads (6%) | called by muse, mutect2
- TENM1 | c.6066T>A p.I2022= | Silent (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- TEX13C | c.2868A>T p.P956= | Silent (SNP) | VAF 26/691 reads (4%) | called by muse, mutect2
- TFAP2C | c.474C>T p.A158= | Silent (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- THSD7B | c.1872G>A p.G624= | Silent (SNP) | VAF 14/326 reads (4%) | called by muse, mutect2
- TIAM2 | c.3612C>T p.F1204= | Silent (SNP) | VAF 18/545 reads (3%) | called by muse, mutect2
- TPTE | c.345C>T p.F115= (on ENST00000618007 / NM_199261.4; = p.F97= on NM_199259.4) | Silent (SNP) | VAF 40/968 reads (4%) | called by muse, mutect2
- TRPV5 | c.234G>T p.L78= | Silent (SNP) | VAF 30/187 reads (16%) | catalogued as COSV54688295; called by muse, mutect2, varscan2
- TUBGCP2 | c.984C>A p.I328= | Silent (SNP) | VAF 14/348 reads (4%) | called by muse, mutect2
- WNK3 | c.1458C>T p.D486= | Silent (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- WNT3 | c.636G>T p.S212= | Silent (SNP) | VAF 6/121 reads (5%) | catalogued as rs1422054724, COSV56646118; called by muse, mutect2
- ZEB1 | c.552T>C p.S184= | Silent (SNP) | VAF 29/956 reads (3%) | called by muse, mutect2
- ZNF536 | c.2832C>A p.P944= | Silent (SNP) | VAF 50/265 reads (19%) | called by muse, mutect2, varscan2
- ZNF699 | c.1768C>T p.L590= | Silent (SNP) | VAF 30/453 reads (7%) | catalogued as COSV100427006; called by muse, mutect2
- ZSCAN12 | c.1395G>C p.G465= | Silent (SNP) | VAF 16/453 reads (4%) | called by muse, mutect2
- AASDHPPT | c.*12G>T | 3'UTR (SNP) | VAF 32/469 reads (7%) | catalogued as rs1281479912; called by muse, mutect2
- AC093582.1 | n.480C>T | RNA (SNP) | VAF 32/204 reads (16%) | catalogued as rs1321254560; called by muse, mutect2, varscan2
- ACOT9 | c.119-1124G>T | Intron (SNP) | VAF 28/386 reads (7%) | called by muse, mutect2
- ACOT9 | c.-12C>A | 5'UTR (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- ACSF3 | c.1614-2952G>T | Intron (SNP) | VAF 41/592 reads (7%) | called by muse, mutect2
- AIRE | c.880-304C>A | Intron (SNP) | VAF 40/406 reads (10%) | called by muse, mutect2
- AL162726.3 | n.255+83782C>A | Intron (SNP) | VAF 65/444 reads (15%) | called by muse, mutect2, varscan2
- AMPH | c.1182+1026G>A | Intron (SNP) | VAF 52/763 reads (7%) | called by muse, mutect2
- ARHGEF4 | chr2:130916439 G>T | 5'Flank (SNP) | VAF 5/35 reads (14%) | catalogued as rs1199657474; called by muse, mutect2, varscan2
- CCDC110 | chr4:185472213 A>G | 5'Flank (SNP) | VAF 46/440 reads (10%) | catalogued as rs778005058; called by muse, mutect2
- CCDC178 | c.2523+16382G>A | Intron (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- CLDN1 | c.*49A>G | 3'UTR (SNP) | VAF 76/511 reads (15%) | called by muse, mutect2, varscan2
- CLRN1 | c.254-3875C>A | Intron (SNP) | VAF 60/206 reads (29%) | called by muse, mutect2, varscan2
- CNPY1 | c.241+10C>T | Intron (SNP) | VAF 85/780 reads (11%) | called by muse, mutect2
- DBT | c.940-37A>G | Intron (SNP) | VAF 45/452 reads (10%) | called by muse, mutect2
- DEPDC5 | c.*948G>A | 3'UTR (SNP) | VAF 38/544 reads (7%) | catalogued as rs373645855; called by muse, mutect2
- DIO3 | chr14:101558480 C>A | 5'Flank (SNP) | VAF 18/121 reads (15%) | called by muse, mutect2, varscan2
- EPRS1 | c.1494+323G>T | Intron (SNP) | VAF 23/374 reads (6%) | catalogued as rs1343415951; called by muse, mutect2
- FAAP100 | c.1404-133T>G | Intron (SNP) | VAF 6/54 reads (11%) | catalogued as rs1375810438; called by muse, mutect2
- FAM3C | c.*62G>T | 3'UTR (SNP) | VAF 75/645 reads (12%) | called by muse, mutect2, varscan2
- FAM78A | c.323+5339A>C | Intron (SNP) | VAF 31/399 reads (8%) | called by muse, mutect2
- FEZ1 | c.-46+658G>A | Intron (SNP) | VAF 24/304 reads (8%) | called by muse, mutect2
- FUBP1 | c.212-830C>A | Intron (SNP) | VAF 23/350 reads (7%) | called by muse, mutect2
- GTF2IRD2P1 | n.1242C>A | RNA (SNP) | VAF 52/534 reads (10%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.1241C>A | RNA (SNP) | VAF 49/527 reads (9%) | called by muse, mutect2, varscan2
- GUCY2EP | n.977C>A | RNA (SNP) | VAF 32/342 reads (9%) | called by muse, mutect2
- HAND2 | c.555+14G>T | Intron (SNP) | VAF 32/350 reads (9%) | called by muse, mutect2
- HNRNPA3P1 | n.680G>C | RNA (SNP) | VAF 104/954 reads (11%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-408G>A | Intron (SNP) | VAF 29/348 reads (8%) | catalogued as COSV55165579; called by muse, mutect2
- IL31RA | c.1501+124C>T | Intron (SNP) | VAF 46/322 reads (14%) | called by muse, mutect2, varscan2
- KCNT2 | c.2349-1215C>A | Intron (SNP) | VAF 32/333 reads (10%) | called by muse, mutect2
- KLHL14 | c.-43-381C>G | Intron (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2, varscan2
- LINC01164 | n.868A>T | RNA (SNP) | VAF 87/681 reads (13%) | called by muse, mutect2, varscan2
- LY6E | c.-20G>T | 5'UTR (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+296T>G | Intron (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- MED15 | c.209-603C>T | Intron (SNP) | VAF 15/91 reads (16%) | called by muse, mutect2, varscan2
- MFRP | chr11:119343843 C>A | 5'Flank (SNP) | VAF 47/492 reads (10%) | called by muse, mutect2
- MIR124-2 | chr8:64378139 T>C | 5'Flank (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- MIR296 | n.13G>C | RNA (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- NUP62CL | c.*77G>T | 3'UTR (SNP) | VAF 82/850 reads (10%) | called by muse, mutect2
- NYNRIN | c.*838G>T | 3'UTR (SNP) | VAF 27/234 reads (12%) | called by muse, mutect2, varscan2
- OBSCN | c.11660-2466A>T | Intron (SNP) | VAF 21/209 reads (10%) | called by muse, mutect2, varscan2
- OR2L1P | n.702C>A | RNA (SNP) | VAF 32/448 reads (7%) | called by muse, mutect2
- POLA1 | c.2549-903G>A | Intron (SNP) | VAF 43/428 reads (10%) | called by muse, mutect2, varscan2
- POM121L4P | n.1132del | RNA (DEL) | VAF 58/433 reads (13%) | called by mutect2, pindel, varscan2
- RANGRF | c.438-13C>T | Intron (SNP) | VAF 28/449 reads (6%) | catalogued as rs1443058243; called by muse, mutect2
- RCC1 | c.-317C>A | 5'UTR (SNP) | VAF 45/479 reads (9%) | called by muse, mutect2
- RPS26P15 | n.69C>A | RNA (SNP) | VAF 53/428 reads (12%) | called by muse, mutect2, varscan2
- SCN5A | c.612-227T>C | Intron (SNP) | VAF 42/254 reads (17%) | called by muse, mutect2, varscan2
- SDSL | c.-143-919G>T | Intron (SNP) | VAF 36/434 reads (8%) | catalogued as rs961970836; called by muse, mutect2
- SEC61A2 | c.-104C>T | 5'UTR (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- SNCB | c.163+9C>A | Intron (SNP) | VAF 47/413 reads (11%) | called by muse, mutect2, varscan2
- SSPOP | n.7552G>A | RNA (SNP) | VAF 20/199 reads (10%) | called by muse, mutect2
- SSPOP | n.9275G>C | RNA (SNP) | VAF 61/384 reads (16%) | catalogued as COSV100948203, COSV65126999; called by muse, mutect2, varscan2
- ST7 | c.151+5491G>C | Intron (SNP) | VAF 67/385 reads (17%) | called by muse, mutect2, varscan2
- SULT1E1 | c.496+10G>T | Intron (SNP) | VAF 60/470 reads (13%) | called by muse, mutect2, varscan2
- SWI5 | c.-53G>C | 5'UTR (SNP) | VAF 12/175 reads (7%) | called by muse, mutect2
- TBC1D15 | c.-30C>T | 5'UTR (SNP) | VAF 36/660 reads (5%) | called by muse, mutect2
- TLCD3B | chr16:30036226 G>A | 5'Flank (SNP) | VAF 67/466 reads (14%) | called by muse, mutect2, varscan2
- TOP1 | c.-66_-61del | 5'UTR (DEL) | VAF 10/70 reads (14%) | called by mutect2, pindel, varscan2
- TRHDE | chr12:72271939 C>A | 5'Flank (SNP) | VAF 59/279 reads (21%) | called by muse, mutect2, varscan2
- USP11 | c.2286+14C>A | Intron (SNP) | VAF 26/195 reads (13%) | called by muse, mutect2, varscan2
